CPTAC case C3N-02330 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4520fa85-cfa5-4d32-86cb-bb5d58c9ada6

Demographics
Sex at birth: female; Race: white; Year of birth: 1966; Vital status: Dead; Days to death: 454 days (1.2 years); Year of death: 2018; Cause of death: Cancer Related; Country of birth: Ukraine.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of trunk; Age at diagnosis: 51.3 years (18,726 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IB; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 454 days (1.2 years); Progression or recurrence: yes; Days to last follow up: 454 days (1.2 years); Tumor focality: Unifocal.
   Pathology details: Breslow thickness category: >1.0-2.0 mm; Greatest tumor dimension: 3 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Lymphatic invasion present: No; Margin status: Uninvolved; Vascular invasion present: No.

Follow-up (2 entries)
- Days to follow up: 210 days; Disease response: With Tumor.
- Days to follow up: 454 days (1.2 years); Disease response: With Tumor.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02330-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -11 days; Initial weight: 370 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02330-23: Section location: Trunk; Percent tumor nuclei: 90; Percent necrosis: 2.
- Sample C3N-02330-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -11 days; Initial weight: 200 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-02330-72: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -11 days; Method of sample procurement: Blood Draw.
